Somatic mutation profile of tumor specimen 0DVZ1L from CCDI case PBCLPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.3 years (9,236 days).
Specimen 0DVZ1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c51ec0f1-3e34-446b-8634-169594d549cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5caf99c6-2f9f-4953-b3a2-472b1a795672

The open-access MAF lists 70 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, Intron 8, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 2, RNA 1, Splice Region 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 98/203 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 174/447 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 198/224 reads (88%) | catalogued as COSV64881511; called by muse, mutect2, varscan2
- B3GNT7 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 190/323 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs373797673; called by muse, mutect2, varscan2
- CRYBG1 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs140546725; called by muse, mutect2, varscan2
- DPP4 | c.1928G>C p.G643A | Missense Mutation (SNP) | VAF 14/467 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62109211; called by muse, mutect2
- EXD1 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 76/473 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV59254121; called by muse, mutect2, varscan2
- IL9 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 17/532 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1467471774; called by muse, mutect2
- KDM6A | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 119/225 reads (53%) | catalogued as COSV65038473, COSV65045993; called by muse, mutect2, varscan2
- MGAT4B | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.997); catalogued as COSV52976777; called by muse, mutect2
- MOCS1 | c.124-5C>T | Splice Region (SNP) | VAF 42/449 reads (9%) | catalogued as rs745669044; called by muse, mutect2
- MSN | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100814190; called by muse, mutect2, varscan2
- PAPSS1 | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 147/359 reads (41%) | catalogued as rs779557704; called by muse, mutect2, varscan2
- ROS1 | c.3418G>A p.A1140T | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100876356; called by muse, mutect2, varscan2
- TP53 | c.420del p.C141Afs*29 | Frame Shift Del (DEL) | VAF 138/383 reads (36%) | catalogued as COSV52700425; called by mutect2, pindel, varscan2
- UBAP2L | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 156/360 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs538113773, COSV55175744, COSV55181277; called by muse, mutect2, varscan2
- ABCB5 | c.2345C>A p.A782D (on ENST00000404938 / NM_001163941.2; = p.A337D on NM_178559.6) | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- AMOTL1 | c.2097C>G p.H699Q | Missense Mutation (SNP) | VAF 23/434 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.137); called by muse, mutect2
- ERMARD | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HS3ST4 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2
- KANK4 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2
- KCNH7 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- MAP2 | c.3371C>G p.A1124G | Missense Mutation (SNP) | VAF 159/361 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MAPK8IP2 | c.702C>G p.S234R | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MBIP | c.806G>T p.R269I | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OGFRL1 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- OGG1 | c.1158_1161del p.S389Lfs*8 | Frame Shift Del (DEL) | VAF 73/478 reads (15%) | called by mutect2, pindel, varscan2
- OR2M4 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 154/374 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PARG | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 60/580 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, varscan2
- PBLD | c.383C>G p.A128G | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2
- PIKFYVE | c.5871G>C p.R1957S | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRSS41 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 245/1179 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- R3HDM1 | c.601A>G p.M201V | Missense Mutation (SNP) | VAF 68/441 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ROCK1 | c.3779A>G p.E1260G | Missense Mutation (SNP) | VAF 214/748 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, varscan2
- SCRIB | c.3833G>C p.G1278A | Missense Mutation (SNP) | VAF 43/414 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SKOR2 | c.372G>C p.E124D | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC22A2 | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SLFN14 | c.94A>G p.M32V | Missense Mutation (SNP) | VAF 85/384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SNAP91 | c.2255C>G p.A752G | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- SNX5 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 107/269 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SSC4D | c.1676C>G p.A559G | Missense Mutation (SNP) | VAF 43/396 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SUPT20H | c.983G>C p.W328S (on ENST00000350612 / NM_001014286.3; = p.W329S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2
- TULP2 | c.32+1G>A p.X11_splice | Splice Site (SNP) | VAF 96/172 reads (56%) | called by muse, mutect2, varscan2
- WIPF2 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFHX3 | c.7018A>C p.I2340L | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2
- ZNF316 | c.2270C>G p.A757G | Missense Mutation (SNP) | VAF 35/343 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ZPLD1 | c.907G>A p.A303T (on ENST00000466937 / NM_001329788.1; = p.A319T on NM_175056.2) | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ACLY | c.330C>T p.F110= | Silent (SNP) | VAF 19/339 reads (6%) | catalogued as rs146805244; called by muse, mutect2
- ANAPC2 | c.1425C>T p.G475= | Silent (SNP) | VAF 146/365 reads (40%) | catalogued as rs1247414844; called by muse, mutect2, varscan2
- ATRX | c.1278G>A p.E426= | Silent (SNP) | VAF 239/262 reads (91%) | called by muse, mutect2, varscan2
- CHD8 | c.3189T>C p.A1063= (on ENST00000646647 / NM_001170629.2; = p.A784= on NM_020920.4) | Silent (SNP) | VAF 30/582 reads (5%) | called by muse, mutect2
- CHST4 | c.132C>T p.H44= | Silent (SNP) | VAF 137/534 reads (26%) | catalogued as rs778197647; called by muse, mutect2, varscan2
- NRIP1 | c.2151G>A p.L717= | Silent (SNP) | VAF 78/487 reads (16%) | called by muse, mutect2, varscan2
- OR10K2 | c.750C>T p.V250= | Silent (SNP) | VAF 140/369 reads (38%) | catalogued as rs1192831166; called by muse, mutect2, varscan2
- PRR22 | c.469C>T p.L157= | Silent (SNP) | VAF 148/565 reads (26%) | called by muse, mutect2, varscan2
- PTPN12 | c.1341A>T p.P447= | Silent (SNP) | VAF 40/325 reads (12%) | called by muse, mutect2, varscan2
- ROCK1 | c.3645A>G p.V1215= | Silent (SNP) | VAF 134/400 reads (34%) | catalogued as COSV67700096; called by muse, varscan2
- ZBTB10 | c.1578C>T p.G526= | Silent (SNP) | VAF 210/499 reads (42%) | called by muse, mutect2, varscan2
- C2orf91 | n.541T>G | RNA (SNP) | VAF 56/319 reads (18%) | called by muse, mutect2
- CARD10 | c.1948-93G>A | Intron (SNP) | VAF 12/86 reads (14%) | catalogued as rs939203411; called by muse, mutect2, varscan2
- CHD7 | c.8077-31A>G | Intron (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- DUT | c.*50A>G | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by mutect2, varscan2
- GCLC | c.1090+76G>C | Intron (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- PSMD5 | c.1006+33T>G | Intron (SNP) | VAF 42/157 reads (27%) | called by muse, mutect2, varscan2
- RALGDS | c.2455-22T>C | Intron (SNP) | VAF 15/89 reads (17%) | catalogued as rs1238842460; called by muse, mutect2, varscan2
- RASEF | c.-25C>G | 5'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- RDM1 | c.-13C>T | 5'UTR (SNP) | VAF 43/207 reads (21%) | catalogued as rs770350030; called by muse, mutect2, varscan2
- TFAP2A | c.486+13G>A | Intron (SNP) | VAF 79/307 reads (26%) | called by muse, mutect2, varscan2
- VAV1 | c.927+86T>C | Intron (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- VIM | c.1273+98C>A | Intron (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
